Somatic mutation profile of tumor specimen MP2PRT-PARNTW-TMP1-A (aliquot MP2PRT-PARNTW-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PARNTW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Blood; Age at diagnosis: 3.0 years (1,111 days).
Specimen MP2PRT-PARNTW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ad73c77-6259-4294-862c-88e17861b53f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARNTW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARNTW-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07ea6e2d-2a77-4071-a283-72267fd4fd21

The open-access MAF lists 344 somatic variants for this specimen: 249 protein-altering or splice-affecting, 75 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 217, Silent 75, Nonsense Mutation 27, Intron 10, 3'Flank 5, 5'Flank 3, Frame Shift Del 2, Splice Site 2, Splice Region 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 18/164 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs1057519725, COSV55498939; ClinVar: not provided / pathogenic; called by muse, varscan2
- KRAS | c.57G>C p.L19F | Missense Mutation (SNP) | VAF 68/442 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs121913538, CM155383, COSV55502103, COSV55521217; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC099489.1 | c.2735C>G p.S912C | Missense Mutation (SNP) | VAF 38/386 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1384383899; called by muse, mutect2
- ACTR1A | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 27/278 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as COSV64023474; called by muse, mutect2, varscan2
- ADAM33 | c.2284C>A p.H762N | Missense Mutation (SNP) | VAF 92/825 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV100597745; called by muse, mutect2, varscan2
- ADGRV1 | c.7289C>T p.S2430F | Missense Mutation (SNP) | VAF 70/494 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1489758170; called by muse, mutect2, varscan2
- APC2 | c.1854-1G>A p.X618_splice | Splice Site (SNP) | VAF 140/373 reads (38%) | catalogued as COSV52018072; called by muse, mutect2, varscan2
- ARFGEF1 | c.3799C>G p.Q1267E | Missense Mutation (SNP) | VAF 82/249 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV51613996, COSV99144732; called by muse, varscan2
- ARMC4 | c.2053G>A p.E685K | Missense Mutation (SNP) | VAF 46/609 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as rs777280534; called by muse, mutect2
- ATN1 | c.1712C>G p.S571C | Missense Mutation (SNP) | VAF 86/613 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.75); catalogued as rs782465676, COSV63110196, COSV63112331; called by muse, mutect2, varscan2
- ATXN2L | c.3021G>C p.Q1007H | Missense Mutation (SNP) | VAF 180/558 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100293785; called by mutect2, varscan2
- AXIN1 | c.1156C>T p.Q386* | Nonsense Mutation (SNP) | VAF 102/642 reads (16%) | catalogued as COSV99250548; called by muse, mutect2, varscan2
- BLM | c.793G>C p.E265Q | Missense Mutation (SNP) | VAF 45/259 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.272); catalogued as COSV61923628; called by muse, mutect2, varscan2
- BUD31 | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 38/253 reads (15%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.856); catalogued as COSV99463259; called by muse, mutect2, varscan2
- C16orf87 | c.13C>G p.R5G | Missense Mutation (SNP) | VAF 31/563 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as COSV99587569; called by muse, mutect2
- C4orf45 | c.182C>G p.S61* | Nonsense Mutation (SNP) | VAF 21/263 reads (8%) | catalogued as COSV101465168; called by muse, mutect2
- C9orf131 | c.1721G>A p.R574K | Missense Mutation (SNP) | VAF 52/429 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as COSV56614538; called by muse, mutect2, varscan2
- CADPS2 | c.164G>A p.R55K | Missense Mutation (SNP) | VAF 104/810 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as rs1158141537; called by muse, mutect2, varscan2
- CALCOCO1 | c.1996G>A p.E666K | Missense Mutation (SNP) | VAF 186/536 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.104); catalogued as rs1304950071; called by muse, mutect2, varscan2
- CARMIL3 | c.3742G>A p.E1248K | Missense Mutation (SNP) | VAF 59/479 reads (12%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.903); catalogued as COSV53743658; called by muse, mutect2, varscan2
- CD101 | c.1759C>G p.H587D | Missense Mutation (SNP) | VAF 72/594 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.023); catalogued as COSV56718245; called by muse, mutect2
- CDH6 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 70/337 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99417977; called by muse, mutect2, varscan2
- CEP192 | c.4994C>G p.S1665* | Nonsense Mutation (SNP) | VAF 64/470 reads (14%) | catalogued as rs1179701588, COSV100381008; called by muse, mutect2, varscan2
- CHFR | c.426C>G p.F142L | Missense Mutation (SNP) | VAF 20/461 reads (4%) | SIFT tolerated (0.66); PolyPhen benign (0.039); catalogued as COSV99905426; called by muse, mutect2
- COBL | c.2491G>A p.E831K | Missense Mutation (SNP) | VAF 144/919 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.468); catalogued as rs779351564; called by muse, mutect2, varscan2
- CSMD3 | c.3070C>G p.H1024D (on ENST00000297405 / NM_001363185.1; = p.H920D on NM_052900.3) | Missense Mutation (SNP) | VAF 106/335 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.158); catalogued as COSV52219274, COSV99847264; called by muse, mutect2, varscan2
- CTAGE1 | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 48/345 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV66945653; called by muse, mutect2, varscan2
- CTTNBP2 | c.3074C>T p.S1025F | Missense Mutation (SNP) | VAF 82/512 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.736); catalogued as rs971651941; called by muse, mutect2, varscan2
- DCBLD2 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.908); catalogued as COSV100472825; called by muse, mutect2
- DST | c.17284C>G p.Q5762E (on ENST00000361203 / NM_001374722.1; = p.Q3459E on NM_015548.5) | Missense Mutation (SNP) | VAF 46/262 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1463234518; called by muse, varscan2
- DST | c.17185G>C p.D5729H (on ENST00000361203 / NM_001374722.1; = p.D3426H on NM_015548.5) | Missense Mutation (SNP) | VAF 35/252 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV55025709; called by muse, varscan2
- EEF2 | c.1353C>G p.I451M | Missense Mutation (SNP) | VAF 24/356 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); catalogued as rs1372164303, COSV58580445; called by muse, mutect2
- ELF4 | c.1729C>T p.Q577* | Nonsense Mutation (SNP) | VAF 37/1044 reads (4%) | catalogued as COSV57451604; called by muse, mutect2
- ERC1 | c.2334G>C p.K778N (on ENST00000360905 / NM_178040.4; = p.K750N on NM_178039.4) | Missense Mutation (SNP) | VAF 15/248 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100705589; called by muse, mutect2
- EVX1 | c.151C>T p.R51W | Missense Mutation (SNP) | VAF 139/714 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV56085191; called by muse, mutect2, varscan2
- EZH2 | c.844C>G p.H282D | Missense Mutation (SNP) | VAF 80/440 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100234659; called by muse, varscan2
- F13B | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV66373357; called by muse, mutect2, varscan2
- F5 | c.4351C>G p.L1451V | Missense Mutation (SNP) | VAF 79/240 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.084); catalogued as COSV63122320; called by muse, mutect2, varscan2
- FAT1 | c.9820G>A p.E3274K | Missense Mutation (SNP) | VAF 44/244 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71673046; called by muse, mutect2
- FGF20 | c.237C>G p.I79M | Missense Mutation (SNP) | VAF 116/832 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1266708845; called by muse, mutect2, varscan2
- FHOD3 | c.522G>C p.Q174H | Missense Mutation (SNP) | VAF 24/209 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1292450166; called by muse, mutect2, varscan2
- FLG | c.10712C>G p.S3571* | Nonsense Mutation (SNP) | VAF 84/602 reads (14%) | catalogued as rs775664986; called by muse, mutect2, varscan2
- GPR1 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 77/341 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.967); catalogued as COSV101329857; called by muse, mutect2, varscan2
- GSPT2 | c.1876G>C p.E626Q | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV100468033, COSV61214173; called by muse, mutect2, varscan2
- HECW2 | c.4578del p.K1527Nfs*34 | Frame Shift Del (DEL) | VAF 111/359 reads (31%) | catalogued as COSV99647402; called by mutect2, pindel, varscan2
- HGF | c.1037G>A p.C346Y | Missense Mutation (SNP) | VAF 29/305 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766585116, COSV55948116; called by muse, mutect2
- HMSD | c.127C>T p.Q43* | Nonsense Mutation (SNP) | VAF 60/378 reads (16%) | catalogued as rs1444467295; called by muse, mutect2, varscan2
- INPP5B | c.2195C>G p.S732C (on ENST00000373023; = p.S652C on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/223 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs1216972173, COSV65962565; called by muse, mutect2, varscan2
- IQCB1 | c.1067G>C p.R356T | Missense Mutation (SNP) | VAF 45/385 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV60437127; called by muse, mutect2, varscan2
- ISOC1 | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 49/367 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.782); catalogued as rs940266140, COSV51491321, COSV99434289; called by muse, mutect2, varscan2
- KCNU1 | c.89C>G p.S30C | Missense Mutation (SNP) | VAF 59/516 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV67754565; called by muse, mutect2, varscan2
- KDM6B | c.644C>G p.S215* | Nonsense Mutation (SNP) | VAF 27/752 reads (4%) | catalogued as COSV54683999; called by muse, mutect2
- KIAA1109 | c.3698C>T p.S1233L | Missense Mutation (SNP) | VAF 56/341 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as rs1443646691, COSV52669190; called by muse, mutect2, varscan2
- KIAA1217 | c.3583G>C p.E1195Q | Missense Mutation (SNP) | VAF 27/368 reads (7%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.937); catalogued as COSV56823260; called by muse, mutect2
- KIAA1522 | c.1736C>G p.S579C (on ENST00000373480 / NM_001198972.2; = p.S638C on NM_020888.3) | Missense Mutation (SNP) | VAF 22/676 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV53868067; called by muse, mutect2
- LENG9 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 32/930 reads (3%) | SIFT tolerated (0.35); PolyPhen benign (0.043); catalogued as rs1321538146; called by muse, mutect2
- LPIN2 | c.1316C>G p.S439C | Missense Mutation (SNP) | VAF 80/493 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV55244139; called by muse, mutect2, varscan2
- MAGEB18 | c.826C>T p.H276Y | Missense Mutation (SNP) | VAF 77/642 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.023); catalogued as rs913130609, COSV57465091; called by muse, mutect2, varscan2
- MCC | c.489G>C p.Q163H | Missense Mutation (SNP) | VAF 16/467 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as rs1293947187, COSV56737403; called by muse, mutect2
- MCM3AP | c.80C>G p.S27C | Missense Mutation (SNP) | VAF 80/438 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.137); catalogued as COSV52440854; called by muse, mutect2, varscan2
- MUC4 | c.11284C>G p.L3762V | Missense Mutation (SNP) | VAF 151/724 reads (21%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.096); catalogued as COSV57780480; called by muse, varscan2
- MUC4 | c.1811G>C p.R604T | Missense Mutation (SNP) | VAF 87/803 reads (11%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.234); catalogued as rs779893185; called by muse, mutect2, varscan2
- NCKAP5 | c.3157A>T p.T1053S | Missense Mutation (SNP) | VAF 185/438 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as rs761168942; called by muse, mutect2, varscan2
- NHSL1 | c.3088C>G p.L1030V | Missense Mutation (SNP) | VAF 84/698 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.91); catalogued as COSV58677564; called by muse, mutect2, varscan2
- NLK | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 71/560 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.051); catalogued as rs750570222; called by muse, mutect2, varscan2
- NPR3 | c.741C>G p.I247M | Missense Mutation (SNP) | VAF 136/374 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as rs753725976, COSV54083925, COSV54087160; called by muse, mutect2, varscan2
- NRG3 | c.1978G>C p.E660Q (on ENST00000404547 / NM_001370084.1; = p.E636Q on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 64/413 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100931269; called by muse, mutect2
- OR1C1 | c.805G>C p.E269Q | Missense Mutation (SNP) | VAF 16/436 reads (4%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.487); catalogued as COSV68715803; called by muse, mutect2
- OVOL2 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 107/1001 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1386080637; called by muse, mutect2, varscan2
- P2RX7 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 73/490 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.419); catalogued as rs768324043; called by muse, mutect2, varscan2
- PC | c.2574C>G p.N858K | Missense Mutation (SNP) | VAF 24/504 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV58992736; called by muse, mutect2
- PDE4B | c.539G>C p.R180T | Missense Mutation (SNP) | VAF 9/289 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV100302532; called by muse, mutect2
- PDS5B | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 50/233 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.604); catalogued as COSV100220413; called by muse, mutect2, varscan2
- PDZRN4 | c.1233A>C p.Q411H (on ENST00000402685 / NM_001164595.2; = p.Q153H on NM_013377.4) | Missense Mutation (SNP) | VAF 108/316 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV54210219; called by muse, mutect2, varscan2
- PGGT1B | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 159/412 reads (39%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.018); catalogued as COSV65472689; called by muse, mutect2, varscan2
- PGR | c.1937G>C p.R646T | Missense Mutation (SNP) | VAF 54/388 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.724); catalogued as rs753321148, COSV54795396; called by muse, mutect2, varscan2
- PIK3CA | c.821G>C p.R274T | Missense Mutation (SNP) | VAF 48/226 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as COSV55992931; called by muse, mutect2, varscan2
- PKN1 | c.2191C>G p.L731V | Missense Mutation (SNP) | VAF 50/464 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99466635; called by muse, varscan2
- PLPPR5 | c.796C>T p.L266= | Splice Region (SNP) | VAF 20/148 reads (14%) | catalogued as rs1173106936; called by muse, mutect2, varscan2
- PVR | c.542C>G p.S181* | Nonsense Mutation (SNP) | VAF 111/664 reads (17%) | catalogued as COSV51824276; called by muse, mutect2, varscan2
- RAPGEF4 | c.754G>A p.V252I | Missense Mutation (SNP) | VAF 28/716 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.119); catalogued as rs1344991981; called by muse, mutect2
- RELL2 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 73/491 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs368112224; called by muse, mutect2, varscan2
- RGPD4 | c.2407C>T p.R803* | Nonsense Mutation (SNP) | VAF 14/99 reads (14%) | catalogued as rs570623065; called by muse, mutect2, varscan2
- RNF17 | c.3152C>T p.S1051L | Missense Mutation (SNP) | VAF 32/286 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as COSV55036479; called by muse, mutect2, varscan2
- RS1 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 57/541 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs281865367, CM981775, CM991119, COSV66106055; ClinVar: not provided; called by muse, mutect2, varscan2
- SCN9A | c.3169G>C p.D1057H (on ENST00000303354; = p.D1046H on NM_002977.3) | Missense Mutation (SNP) | VAF 53/386 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs370892430; called by muse, mutect2, varscan2
- SCYL3 | c.1108C>G p.Q370E | Missense Mutation (SNP) | VAF 77/434 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as rs754974082; called by muse, mutect2, varscan2
- SETD2 | c.1535C>G p.S512* | Nonsense Mutation (SNP) | VAF 8/183 reads (4%) | catalogued as COSV57437123; called by muse, mutect2
- SLC13A1 | c.948C>G p.F316L | Missense Mutation (SNP) | VAF 65/229 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.103); catalogued as COSV52011045; called by muse, mutect2, varscan2
- SLC1A7 | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 20/614 reads (3%) | catalogued as COSV101019456; called by muse, mutect2
- SLC4A3 | c.955C>T p.H319Y | Missense Mutation (SNP) | VAF 64/446 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as rs765212562; called by muse, mutect2, varscan2
- SLC8A1 | c.1936G>C p.G646R | Missense Mutation (SNP) | VAF 23/246 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.062); catalogued as COSV100245565, COSV60469709, COSV60473783; called by muse, mutect2
- SPHK2 | c.1588G>A p.D530N | Missense Mutation (SNP) | VAF 134/756 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.013); catalogued as rs367741165; called by muse, mutect2, varscan2
- SPHKAP | c.2626G>A p.E876K | Missense Mutation (SNP) | VAF 36/345 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs1467681966; called by muse, mutect2, varscan2
- STK26 | c.127G>C p.D43H | Missense Mutation (SNP) | VAF 75/416 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.684); catalogued as COSV61230351; called by muse, mutect2, varscan2
- STK39 | c.1289C>T p.S430F | Missense Mutation (SNP) | VAF 55/401 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.396); catalogued as rs773594176, COSV63597218; called by muse, mutect2, varscan2
- SULF1 | c.919G>C p.E307Q | Missense Mutation (SNP) | VAF 85/388 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as COSV99484360; called by muse, mutect2, varscan2
- SUZ12 | c.2192C>G p.S731* | Nonsense Mutation (SNP) | VAF 19/255 reads (7%) | catalogued as COSV59504036; called by muse, mutect2
- SYNE2 | c.19372G>A p.D6458N | Missense Mutation (SNP) | VAF 59/549 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as rs202052357, COSV59951917; called by muse, mutect2, varscan2
- TACC2 | c.5215G>A p.D1739N | Missense Mutation (SNP) | VAF 78/654 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1187809613; called by muse, mutect2, varscan2
- TENM2 | c.4423G>C p.E1475Q (on ENST00000518659 / NM_001122679.2; = p.E1236Q on NM_001080428.3) | Missense Mutation (SNP) | VAF 82/595 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.928); catalogued as COSV69141867; called by muse, mutect2, varscan2
- TKTL2 | c.453C>G p.F151L | Missense Mutation (SNP) | VAF 97/481 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV54921632; called by muse, mutect2, varscan2
- TNRC6C | c.1259G>A p.R420Q | Missense Mutation (SNP) | VAF 41/526 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as rs537887612, COSV56942102; called by muse, mutect2
- TOP3A | c.2408C>T p.T803M | Missense Mutation (SNP) | VAF 227/593 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.247); catalogued as rs774009141; called by muse, mutect2, varscan2
- TREML4 | c.499G>C p.E167Q | Missense Mutation (SNP) | VAF 86/398 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.07); catalogued as COSV58384580; called by muse, mutect2
- TRIM42 | c.688G>C p.D230H | Missense Mutation (SNP) | VAF 76/577 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53886835; called by muse, mutect2, varscan2
- UBE2R2 | c.315G>C p.Q105H | Missense Mutation (SNP) | VAF 28/192 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.275); catalogued as COSV54291793; called by muse, mutect2, varscan2
- UCHL5 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV66486892; called by muse, mutect2, varscan2
- USP38 | c.2686C>G p.P896A | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as COSV100189242, COSV61026881; called by muse, mutect2
- WWC1 | c.2605G>C p.D869H | Missense Mutation (SNP) | VAF 56/499 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as COSV54649694; called by muse, mutect2, varscan2
- ZC3H15 | c.666G>C p.K222N | Missense Mutation (SNP) | VAF 35/179 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.184); catalogued as rs3211121; called by muse, mutect2, varscan2
- ZNF426 | c.673G>C p.E225Q | Missense Mutation (SNP) | VAF 17/227 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV53468287; called by muse, mutect2
- ZNF679 | c.1091C>G p.S364C | Missense Mutation (SNP) | VAF 30/197 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as rs1284946114; called by muse, mutect2, varscan2
- ABCA5 | c.3058G>C p.E1020Q | Missense Mutation (SNP) | VAF 35/181 reads (19%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- ACADL | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ACRBP | c.1207C>G p.P403A | Missense Mutation (SNP) | VAF 81/539 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACTL8 | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 190/447 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ADAM22 | c.377C>T p.T126I | Missense Mutation (SNP) | VAF 48/196 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AGBL2 | c.2104G>C p.E702Q | Missense Mutation (SNP) | VAF 39/240 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- ANKH | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 39/320 reads (12%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ANO6 | c.76G>C p.E26Q | Missense Mutation (SNP) | VAF 84/309 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- APOB | c.11706G>C p.L3902F | Missense Mutation (SNP) | VAF 24/430 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.604); called by muse, mutect2
- ARHGAP5 | c.3277G>A p.E1093K | Missense Mutation (SNP) | VAF 45/347 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- ASPA | c.120G>C p.E40D | Missense Mutation (SNP) | VAF 138/401 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- ATN1 | c.788C>G p.S263* | Nonsense Mutation (SNP) | VAF 91/547 reads (17%) | called by muse, mutect2, varscan2
- ATP11C | c.1630G>C p.D544H | Missense Mutation (SNP) | VAF 34/384 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BFSP1 | c.1138G>C p.D380H | Missense Mutation (SNP) | VAF 52/376 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- BNC2 | c.1639G>C p.D547H | Missense Mutation (SNP) | VAF 70/465 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- BPTF | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 77/561 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.05); called by muse, varscan2
- C9orf131 | c.830C>G p.S277C | Missense Mutation (SNP) | VAF 77/457 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC88C | c.4062G>T p.E1354D | Missense Mutation (SNP) | VAF 29/617 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); called by muse, mutect2
- CCNO | c.893C>T p.S298L | Missense Mutation (SNP) | VAF 94/744 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CCSER1 | c.2350C>G p.Q784E | Missense Mutation (SNP) | VAF 53/363 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- CCSER2 | c.241G>C p.E81Q | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCT7 | c.781G>C p.E261Q | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.029); called by muse, mutect2
- CDC34 | c.201C>A p.D67E | Missense Mutation (SNP) | VAF 166/529 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CEP170 | c.766G>C p.E256Q | Missense Mutation (SNP) | VAF 55/347 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- CKMT1B | c.1109C>G p.S370C | Missense Mutation (SNP) | VAF 32/319 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLDN25 | c.217C>G p.L73V | Missense Mutation (SNP) | VAF 93/471 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COL14A1 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 70/225 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CPEB1 | c.434C>G p.S145C (on ENST00000617958; = p.S85C on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/643 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- CSMD3 | c.3337C>T p.H1113Y (on ENST00000297405 / NM_001363185.1; = p.H1009Y on NM_052900.3) | Missense Mutation (SNP) | VAF 50/261 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- CUL5 | c.2272G>C p.E758Q | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- DAGLA | c.2193G>C p.M731I | Missense Mutation (SNP) | VAF 96/443 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DUT | c.282G>C p.E94D (on ENST00000331200 / NM_001025248.2; = p.E6D on NM_001948.4) | Missense Mutation (SNP) | VAF 92/628 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- EYS | c.5626C>G p.Q1876E | Missense Mutation (SNP) | VAF 54/310 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- FABP7 | c.349-1G>A p.X117_splice | Splice Site (SNP) | VAF 20/308 reads (6%) | called by muse, mutect2
- FARSA | c.1516G>C p.E506Q | Missense Mutation (SNP) | VAF 57/425 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FCGR1A | c.823G>C p.E275Q | Missense Mutation (SNP) | VAF 47/410 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- FLRT3 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 79/367 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- FSIP2 | c.15205C>G p.Q5069E | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- GDNF | c.163G>C p.E55Q | Missense Mutation (SNP) | VAF 73/197 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- GOLGA8G | c.685G>C p.E229Q | Missense Mutation (SNP) | VAF 14/727 reads (2%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); called by muse, mutect2
- GPKOW | c.598C>G p.P200A | Missense Mutation (SNP) | VAF 65/619 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- H2AC6 | c.122C>G p.A41G | Missense Mutation (SNP) | VAF 23/343 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.383); called by muse, mutect2
- HDAC2 | c.298G>C p.D100H | Missense Mutation (SNP) | VAF 98/277 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HDGFL3 | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 18/146 reads (12%) | called by muse, mutect2, varscan2
- HELQ | c.1828G>A p.E610K | Missense Mutation (SNP) | VAF 11/240 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.01); called by muse, mutect2
- HERC1 | c.10603G>T p.E3535* | Nonsense Mutation (SNP) | VAF 53/574 reads (9%) | called by muse, mutect2
- HEY1 | c.254C>A p.S85Y | Missense Mutation (SNP) | VAF 42/382 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- HSD3B7 | c.514G>C p.E172Q | Missense Mutation (SNP) | VAF 73/429 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- HSF5 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 108/829 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- INPP5E | c.1349G>C p.R450T | Missense Mutation (SNP) | VAF 46/668 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); called by muse, mutect2
- INSM1 | c.1075G>C p.E359Q | Missense Mutation (SNP) | VAF 115/717 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- IRAG1 | c.1249G>C p.E417Q | Missense Mutation (SNP) | VAF 110/594 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- IRAG2 | c.2097G>C p.K699N | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ISYNA1 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 133/627 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- JPH1 | c.58G>C p.E20Q | Missense Mutation (SNP) | VAF 118/772 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- KIF7 | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 94/547 reads (17%) | called by muse, mutect2, varscan2
- KLHDC4 | c.147G>C p.K49N | Missense Mutation (SNP) | VAF 68/494 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- KRBA2 | c.723G>C p.K241N | Missense Mutation (SNP) | VAF 62/477 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- LIMA1 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 82/397 reads (21%) | SIFT tolerated (0.77); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- LRRC37B | c.1423C>T p.P475S | Missense Mutation (SNP) | VAF 51/305 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- LSP1 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 94/605 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MAGEE1 | c.2736G>T p.M912I | Missense Mutation (SNP) | VAF 101/596 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- MAGT1 | c.308C>T p.S103F (on ENST00000618282 / NM_001367916.1; = p.S135F on NM_032121.5) | Missense Mutation (SNP) | VAF 54/344 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- MAP3K6 | c.492C>G p.F164L | Missense Mutation (SNP) | VAF 47/375 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- MCM9 | c.289C>T p.H97Y | Missense Mutation (SNP) | VAF 86/286 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- METTL18 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 47/421 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- MKS1 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 26/298 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); called by muse, mutect2
- MMP24 | c.677C>G p.S226C | Missense Mutation (SNP) | VAF 58/409 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MSL3 | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 174/511 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- MUC5B | c.13748C>G p.S4583C | Missense Mutation (SNP) | VAF 188/1189 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- MUC5B | c.15067G>C p.E5023Q | Missense Mutation (SNP) | VAF 16/561 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.43); called by muse, mutect2
- MYO5C | c.5029G>C p.D1677H | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); called by muse, mutect2
- NAB1 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 75/440 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NDST3 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 45/368 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- NEUROD2 | c.480C>G p.I160M | Missense Mutation (SNP) | VAF 234/647 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NIBAN3 | c.151C>G p.Q51E | Missense Mutation (SNP) | VAF 50/408 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NTN3 | c.1423G>C p.E475Q | Missense Mutation (SNP) | VAF 153/716 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- OBSL1 | c.5617G>C p.E1873Q | Missense Mutation (SNP) | VAF 74/748 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.885); called by muse, mutect2
- OR4K13 | c.475C>G p.Q159E | Missense Mutation (SNP) | VAF 151/405 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- OXGR1 | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 60/477 reads (13%) | called by muse, mutect2, varscan2
- PABPC4L | c.712G>C p.D238H | Missense Mutation (SNP) | VAF 60/425 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- PAGE2 | c.35C>A p.S12* | Nonsense Mutation (SNP) | VAF 22/223 reads (10%) | called by muse, mutect2, varscan2
- PARD6G | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 279/753 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDH11X | c.3925G>T p.E1309* | Nonsense Mutation (SNP) | VAF 224/620 reads (36%) | called by muse, varscan2
- PCLO | c.12080C>G p.S4027* | Nonsense Mutation (SNP) | VAF 63/401 reads (16%) | called by muse, mutect2, varscan2
- PCSK9 | c.1855C>G p.Q619E | Missense Mutation (SNP) | VAF 49/397 reads (12%) | SIFT tolerated (0.88); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDIA2 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 49/421 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- PLA2R1 | c.2664G>A p.W888* | Nonsense Mutation (SNP) | VAF 29/212 reads (14%) | called by muse, mutect2, varscan2
- PLB1 | c.901T>G p.S301A | Missense Mutation (SNP) | VAF 114/568 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLCE1 | c.3161G>T p.W1054L | Missense Mutation (SNP) | VAF 78/539 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- POLQ | c.3966C>G p.F1322L | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- POM121 | c.3572G>C p.G1191A (on ENST00000434423; = p.G926A on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/580 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.375); called by muse, mutect2
- PPP1R3A | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 58/437 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- PREX2 | c.3001C>G p.L1001V | Missense Mutation (SNP) | VAF 89/478 reads (19%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- PRPF4B | c.1810G>C p.E604Q | Missense Mutation (SNP) | VAF 38/361 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PVR | c.694C>G p.Q232E | Missense Mutation (SNP) | VAF 62/380 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- RAPGEF6 | c.2527G>A p.E843K | Missense Mutation (SNP) | VAF 13/352 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); called by muse, mutect2
- RGL2 | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 196/562 reads (35%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- RNF227 | c.308G>C p.R103P | Missense Mutation (SNP) | VAF 114/589 reads (19%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ROBO1 | c.1094G>T p.G365V | Missense Mutation (SNP) | VAF 30/398 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ROPN1L | c.333C>G p.F111L | Missense Mutation (SNP) | VAF 34/558 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- RPS9 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 56/696 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.857); called by muse, mutect2
- RTL9 | c.521C>G p.S174C | Missense Mutation (SNP) | VAF 103/607 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RUFY3 | c.1054G>C p.E352Q | Missense Mutation (SNP) | VAF 46/247 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- RYR3 | c.12280G>C p.E4094Q (on ENST00000389232; = p.E4095Q on NM_001036.6) | Missense Mutation (SNP) | VAF 82/423 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RYR3 | c.12757G>C p.E4253Q (on ENST00000389232; = p.E4254Q on NM_001036.6) | Missense Mutation (SNP) | VAF 54/354 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- SATB2 | c.690G>C p.K230N | Missense Mutation (SNP) | VAF 32/210 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- SCN7A | c.789G>C p.L263F | Missense Mutation (SNP) | VAF 43/469 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- SDK2 | c.1513C>T p.Q505* | Nonsense Mutation (SNP) | VAF 82/472 reads (17%) | called by muse, mutect2, varscan2
- SH3KBP1 | c.1204A>T p.K402* | Nonsense Mutation (SNP) | VAF 121/723 reads (17%) | called by muse, mutect2, varscan2
- SHH | c.1068C>G p.I356M | Missense Mutation (SNP) | VAF 38/992 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2
- SLC22A1 | c.1646C>G p.S549* | Nonsense Mutation (SNP) | VAF 14/428 reads (3%) | called by muse, mutect2
- SMARCA1 | c.2653C>T p.R885* | Nonsense Mutation (SNP) | VAF 32/197 reads (16%) | called by muse, mutect2, varscan2
- ST7 | c.28G>C p.E10Q | Missense Mutation (SNP) | VAF 66/488 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- SYNJ1 | c.3582G>C p.R1194S | Missense Mutation (SNP) | VAF 24/392 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.557); called by muse, mutect2
- SYNPO | c.2228C>G p.S743* (on ENST00000394243 / NM_001166208.2; = p.S499* on NM_007286.6) | Nonsense Mutation (SNP) | VAF 248/692 reads (36%) | called by muse, mutect2, varscan2
- TJP1 | c.3691C>G p.Q1231E | Missense Mutation (SNP) | VAF 84/652 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- TLL1 | c.1022G>A p.R341K | Missense Mutation (SNP) | VAF 47/283 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMPRSS2 | c.109T>C p.Y37H | Missense Mutation (SNP) | VAF 132/766 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- TP53BP2 | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 25/204 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TRIO | c.6229G>C p.D2077H | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRRAP | c.7387G>C p.D2463H (on ENST00000359863 / NM_001244580.1; = p.D2445H on NM_003496.3) | Missense Mutation (SNP) | VAF 49/463 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- UBA1 | c.392C>G p.S131* | Nonsense Mutation (SNP) | VAF 77/508 reads (15%) | called by muse, mutect2, varscan2
- UBA2 | c.53del p.G18Afs*29 | Frame Shift Del (DEL) | VAF 92/550 reads (17%) | called by mutect2, varscan2
- UBA7 | c.2107C>G p.P703A | Missense Mutation (SNP) | VAF 57/361 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- UCP3 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 68/487 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- UNC13C | c.3301G>C p.E1101Q | Missense Mutation (SNP) | VAF 60/459 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- UNC5D | c.1443C>G p.I481M | Missense Mutation (SNP) | VAF 91/598 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- UPK1B | c.348C>G p.F116L | Missense Mutation (SNP) | VAF 32/210 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- VCAN | c.2188C>G p.L730V | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- VLDLR | c.280G>C p.D94H | Missense Mutation (SNP) | VAF 44/512 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.292); called by muse, mutect2
- WFDC1 | c.406G>C p.E136Q | Missense Mutation (SNP) | VAF 46/358 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- WWC2 | c.2731G>C p.E911Q | Missense Mutation (SNP) | VAF 20/650 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.178); called by muse, mutect2
- XRCC4 | c.52C>G p.H18D | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ZFPM2 | c.2803C>T p.H935Y | Missense Mutation (SNP) | VAF 55/465 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- ZPR1 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 92/904 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); called by muse, mutect2
- AC099489.1 | c.708G>A p.L236= | Silent (SNP) | VAF 67/809 reads (8%) | called by muse, mutect2
- AGMO | c.1185C>T p.L395= | Silent (SNP) | VAF 32/363 reads (9%) | called by muse, mutect2
- AKR1E2 | c.369C>T p.F123= | Silent (SNP) | VAF 54/577 reads (9%) | called by muse, mutect2
- ALK | c.4080G>C p.R1360= | Silent (SNP) | VAF 133/442 reads (30%) | called by muse, mutect2, varscan2
- ATF2 | c.204G>A p.Q68= | Silent (SNP) | VAF 18/208 reads (9%) | called by muse, mutect2
- BACH2 | c.1125G>A p.G375= | Silent (SNP) | VAF 73/557 reads (13%) | called by muse, mutect2, varscan2
- BMS1 | c.2274C>T p.F758= | Silent (SNP) | VAF 85/313 reads (27%) | catalogued as rs755586251; called by muse, mutect2, varscan2
- BTG4 | c.267G>A p.P89= | Silent (SNP) | VAF 33/379 reads (9%) | catalogued as rs760997790; called by muse, mutect2
- BTNL3 | c.795C>T p.I265= | Silent (SNP) | VAF 16/455 reads (4%) | called by muse, mutect2
- C9orf131 | c.684C>G p.V228= | Silent (SNP) | VAF 69/395 reads (17%) | catalogued as rs1390588197; called by muse, mutect2, varscan2
- C9orf131 | c.1104C>T p.F368= | Silent (SNP) | VAF 76/538 reads (14%) | called by muse, mutect2, varscan2
- CACNA1D | c.2673C>T p.L891= (on ENST00000350061 / NM_001128840.3; = p.L911= on NM_000720.4) | Silent (SNP) | VAF 75/643 reads (12%) | called by muse, mutect2, varscan2
- CALML5 | c.261C>T p.F87= | Silent (SNP) | VAF 145/1135 reads (13%) | catalogued as rs1167912546; called by muse, mutect2, varscan2
- CAVIN2 | c.711G>A p.K237= | Silent (SNP) | VAF 82/453 reads (18%) | catalogued as rs779526446, COSV58424880; called by muse, mutect2, varscan2
- CBY2 | c.706C>T p.L236= | Silent (SNP) | VAF 17/651 reads (3%) | catalogued as rs913636159; called by muse, mutect2
- CDC42BPA | c.1695G>A p.L565= | Silent (SNP) | VAF 49/370 reads (13%) | catalogued as COSV62018425; called by muse, mutect2, varscan2
- CEP131 | c.66G>C p.L22= | Silent (SNP) | VAF 20/806 reads (2%) | called by muse, mutect2
- CFAP46 | c.1260C>G p.L420= | Silent (SNP) | VAF 15/498 reads (3%) | called by muse, mutect2
- CHI3L1 | c.228C>G p.L76= | Silent (SNP) | VAF 31/267 reads (12%) | called by muse, mutect2, varscan2
- COL17A1 | c.4485C>G p.V1495= | Silent (SNP) | VAF 85/455 reads (19%) | catalogued as COSV59828125; called by muse, mutect2, varscan2
- CSNK1A1L | c.831G>A p.L277= | Silent (SNP) | VAF 144/427 reads (34%) | called by muse, mutect2, varscan2
- DNASE1L2 | c.570G>C p.V190= | Silent (SNP) | VAF 80/611 reads (13%) | catalogued as rs572347132; called by muse, mutect2, varscan2
- DOCK9 | c.4446C>G p.L1482= (on ENST00000376460 / NM_001366676.2; = p.L1483= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 60/462 reads (13%) | called by muse, mutect2, varscan2
- ELF4 | c.1572C>T p.F524= | Silent (SNP) | VAF 29/983 reads (3%) | called by muse, mutect2
- ESYT1 | c.2640C>G p.L880= | Silent (SNP) | VAF 54/514 reads (11%) | catalogued as COSV57273013, COSV99920183; called by muse, mutect2
- FHOD1 | c.2241G>A p.Q747= | Silent (SNP) | VAF 87/494 reads (18%) | catalogued as COSV50759220, COSV50761105; called by muse, mutect2, varscan2
- FRG2 | c.354C>T p.C118= | Silent (SNP) | VAF 63/394 reads (16%) | called by muse, mutect2, varscan2
- FSIP2 | c.20723G>A p.*6908= | Silent (SNP) | VAF 62/168 reads (37%) | called by muse, mutect2, varscan2
- GCFC2 | c.2061C>T p.L687= | Silent (SNP) | VAF 41/311 reads (13%) | called by muse, mutect2, varscan2
- GLIS3 | c.1626G>C p.V542= | Silent (SNP) | VAF 82/535 reads (15%) | called by muse, mutect2, varscan2
- HEATR1 | c.5907G>T p.V1969= | Silent (SNP) | VAF 44/283 reads (16%) | called by muse, mutect2, varscan2
- IP6K1 | c.708G>A p.A236= | Silent (SNP) | VAF 56/519 reads (11%) | catalogued as rs760260548; called by muse, mutect2, varscan2
- JCAD | c.642C>T p.F214= | Silent (SNP) | VAF 42/673 reads (6%) | called by muse, mutect2
- KAZALD1 | c.48C>G p.L16= | Silent (SNP) | VAF 142/836 reads (17%) | called by muse, mutect2, varscan2
- KEL | c.1455C>G p.A485= | Silent (SNP) | VAF 235/637 reads (37%) | called by muse, mutect2, varscan2
- KIAA0319 | c.2106C>T p.S702= | Silent (SNP) | VAF 42/416 reads (10%) | called by muse, mutect2, varscan2
- KIAA1109 | c.6507G>C p.L2169= | Silent (SNP) | VAF 51/378 reads (13%) | called by muse, mutect2, varscan2
- KIAA1217 | c.2244G>A p.L748= | Silent (SNP) | VAF 38/752 reads (5%) | catalogued as COSV56812328; called by muse, mutect2
- KRT72 | c.57C>T p.C19= | Silent (SNP) | VAF 110/691 reads (16%) | catalogued as rs760293148; called by muse, mutect2, varscan2
- LARS1 | c.1209C>T p.L403= (on ENST00000394434 / NM_020117.11; = p.L376= on NM_016460.3) | Silent (SNP) | VAF 109/302 reads (36%) | called by muse, mutect2, varscan2
- MAN1A1 | c.144C>T p.F48= | Silent (SNP) | VAF 103/565 reads (18%) | called by muse, mutect2, varscan2
- MCM5 | c.2025C>T p.I675= | Silent (SNP) | VAF 59/488 reads (12%) | catalogued as rs563110160, COSV99331375; called by muse, mutect2, varscan2
- MIER3 | c.417C>T p.F139= | Silent (SNP) | VAF 65/330 reads (20%) | called by muse, mutect2, varscan2
- MRAP2 | c.246G>A p.E82= | Silent (SNP) | VAF 52/333 reads (16%) | catalogued as COSV100004556, COSV57634882; called by muse, mutect2, varscan2
- MTNR1A | c.246G>A p.P82= | Silent (SNP) | VAF 55/363 reads (15%) | catalogued as rs541660089, COSV56155491; called by muse, mutect2, varscan2
- OR2B11 | c.840C>G p.L280= | Silent (SNP) | VAF 26/390 reads (7%) | catalogued as COSV100275339; called by muse, mutect2
- OR5B3 | c.75C>G p.L25= | Silent (SNP) | VAF 29/311 reads (9%) | catalogued as rs1565152317; called by muse, mutect2, varscan2
- OR5H8 | c.108C>G p.L36= | Silent (SNP) | VAF 33/217 reads (15%) | called by muse, mutect2, varscan2
- OXR1 | c.2349G>A p.L783= (on ENST00000442977 / NM_001198532.1; = p.L755= on NM_018002.3) | Silent (SNP) | VAF 30/318 reads (9%) | catalogued as COSV52424968; called by muse, mutect2
- PAPLN | c.2916C>T p.D972= (on ENST00000554301; = p.D945= on NM_173462.4) | Silent (SNP) | VAF 204/521 reads (39%) | catalogued as rs376194083; called by muse, mutect2, varscan2
- PCTP | c.60C>G p.L20= | Silent (SNP) | VAF 139/913 reads (15%) | called by muse, mutect2, varscan2
- POLQ | c.3669C>A p.V1223= | Silent (SNP) | VAF 8/109 reads (7%) | catalogued as rs1191335104; called by muse, mutect2
- POTEC | c.864G>C p.V288= | Silent (SNP) | VAF 21/137 reads (15%) | catalogued as COSV100743906, COSV62802483; called by muse, mutect2, varscan2
- PRIM2 | c.33G>A p.L11= | Silent (SNP) | VAF 55/357 reads (15%) | catalogued as COSV51424629; called by muse, mutect2, varscan2
- R3HCC1L | c.1794G>A p.L598= | Silent (SNP) | VAF 29/300 reads (10%) | called by muse, mutect2
- RASGRF2 | c.156C>T p.F52= | Silent (SNP) | VAF 125/862 reads (15%) | called by muse, mutect2, varscan2
- RGS3 | c.1329C>G p.T443= (on ENST00000350696 / NM_001282923.2; = p.T331= on NM_017790.4) | Silent (SNP) | VAF 301/771 reads (39%) | catalogued as rs146550810; called by muse, mutect2, varscan2
- RTL8A | c.204C>T p.L68= | Silent (SNP) | VAF 136/801 reads (17%) | catalogued as rs960936476; called by muse, mutect2, varscan2
- SEL1L3 | c.2529C>T p.L843= | Silent (SNP) | VAF 15/411 reads (4%) | called by muse, mutect2
- SIDT1 | c.2232C>G p.L744= | Silent (SNP) | VAF 96/503 reads (19%) | catalogued as rs774194610; called by muse, mutect2, varscan2
- SLC5A1 | c.456C>G p.L152= | Silent (SNP) | VAF 42/397 reads (11%) | called by muse, mutect2, varscan2
- SLCO3A1 | c.1239C>A p.L413= | Silent (SNP) | VAF 80/501 reads (16%) | catalogued as COSV59225550; called by muse, mutect2, varscan2
- SNX25 | c.2028G>T p.G676= | Silent (SNP) | VAF 65/428 reads (15%) | called by muse, mutect2, varscan2
- SPATA24 | c.15C>T p.L5= | Silent (SNP) | VAF 41/340 reads (12%) | catalogued as rs898369687; called by muse, mutect2, varscan2
- SYNPO | c.1995C>T p.F665= (on ENST00000394243 / NM_001166208.2; = p.F421= on NM_007286.6) | Silent (SNP) | VAF 316/835 reads (38%) | catalogued as rs376777866; called by muse, mutect2, varscan2
- SYNPO | c.2541C>G p.P847= (on ENST00000394243 / NM_001166208.2; = p.P603= on NM_007286.6) | Silent (SNP) | VAF 285/804 reads (35%) | called by muse, mutect2, varscan2
- TBX20 | c.738G>C p.L246= | Silent (SNP) | VAF 43/526 reads (8%) | called by muse, mutect2
- TCP11X2 | c.939G>A p.L313= | Silent (SNP) | VAF 50/456 reads (11%) | called by muse, mutect2
- TRAF7 | c.45G>A p.G15= | Silent (SNP) | VAF 70/883 reads (8%) | catalogued as rs763890292, COSV58213663; called by muse, mutect2
- TRPM3 | c.603C>G p.L201= (on ENST00000357533 / NM_001366142.2; = p.L46= on NM_020952.6) | Silent (SNP) | VAF 92/587 reads (16%) | called by muse, mutect2
- VPS45 | c.321G>C p.V107= | Silent (SNP) | VAF 50/378 reads (13%) | called by muse, mutect2, varscan2
- ZKSCAN8 | c.1251G>A p.Q417= | Silent (SNP) | VAF 86/475 reads (18%) | catalogued as COSV57640468; called by muse, mutect2, varscan2
- ZNF256 | c.1278G>A p.Q426= | Silent (SNP) | VAF 10/317 reads (3%) | called by muse, mutect2
- ZNF574 | c.1119C>T p.F373= | Silent (SNP) | VAF 68/703 reads (10%) | catalogued as rs113091672, COSV55903296; called by muse, mutect2, varscan2
- ZSCAN12 | c.1698G>A p.K566= | Silent (SNP) | VAF 35/250 reads (14%) | called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826171 C>T | 3'Flank (SNP) | VAF 63/379 reads (17%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851436 C>T | 3'Flank (SNP) | VAF 45/369 reads (12%) | called by muse, mutect2, varscan2
- CDH23 | c.3369+342G>C | Intron (SNP) | VAF 19/477 reads (4%) | called by muse, mutect2
- CORO6 | c.634-533C>T | Intron (SNP) | VAF 21/649 reads (3%) | called by muse, mutect2
- CRYBG2 | chr1:26356468 G>C | 5'Flank (SNP) | VAF 49/539 reads (9%) | called by muse, mutect2
- DYRK1A | c.1671+32C>T | Intron (SNP) | VAF 94/465 reads (20%) | catalogued as COSV100117934; called by muse, mutect2, varscan2
- FANCD2 | chr3:10101262 G>C | 3'Flank (SNP) | VAF 85/473 reads (18%) | catalogued as COSV55033131; called by muse, mutect2, varscan2
- GABRB3 | c.241-7445G>C | Intron (SNP) | VAF 73/509 reads (14%) | catalogued as rs968241277; called by muse, mutect2, varscan2
- H2BP2 | n.1061+539C>G | Intron (SNP) | VAF 71/321 reads (22%) | called by muse, mutect2, varscan2
- IGHV1-58 | chr14:106627248 ins GTTCTGA | 5'Flank (INS) | VAF 35/163 reads (21%) | called by mutect2, pindel, varscan2
- IGHV3-53 | chr14:106592675 ins A | 3'Flank (INS) | VAF 57/103 reads (55%) | called by mutect2, pindel, varscan2
- IRX5 | c.250-366G>A | Intron (SNP) | VAF 67/589 reads (11%) | catalogued as rs1467883684; called by muse, mutect2, varscan2
- KCNQ1 | c.1394-5056G>A | Intron (SNP) | VAF 28/132 reads (21%) | called by muse, mutect2, varscan2
- LAMTOR5 | chr1:110407700 G>C | 5'Flank (SNP) | VAF 114/800 reads (14%) | called by muse, mutect2, varscan2
- MARVELD3 | chr16:71640536 G>T | 3'Flank (SNP) | VAF 63/562 reads (11%) | called by muse, mutect2, varscan2
- MROH7 | c.2965-204G>A | Intron (SNP) | VAF 84/502 reads (17%) | called by muse, mutect2, varscan2
- PDXK | c.88-1577C>T | Intron (SNP) | VAF 44/424 reads (10%) | called by muse, varscan2
- PGA5 | c.657-40G>A | Intron (SNP) | VAF 115/636 reads (18%) | catalogued as rs368095658, COSV56716306; called by muse, mutect2, varscan2
- SDHAF2 | c.*465G>A | 3'UTR (SNP) | VAF 72/518 reads (14%) | called by muse, mutect2, varscan2
- SYT9 | c.-1G>C | 5'UTR (SNP) | VAF 145/472 reads (31%) | catalogued as COSV59618709; called by muse, mutect2, varscan2
